Somatic mutation profile of tumor specimen TARGET-30-PALUDH-01A (aliquot TARGET-30-PALUDH-01A-01W) from TARGET case TARGET-30-PALUDH, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 3.0 years (1,105 days).
Specimen TARGET-30-PALUDH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e56709ac-c04e-4706-892c-c53b8faefe53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALUDH-10A (Blood Derived Normal), aliquot TARGET-30-PALUDH-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60d771a4-324c-4c20-8e7e-e98ef747e321

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMSAP1 | c.4027G>T p.E1343* | Nonsense Mutation (SNP) | VAF 35/100 reads (35%) | catalogued as COSV56718079; called by muse, mutect2, varscan2
- CTAGE1 | c.1338A>C p.L446F | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.333); catalogued as COSV66942799; called by muse, mutect2, varscan2
- CYP2C8 | c.481+1G>T p.X161_splice | Splice Site (SNP) | VAF 441/1056 reads (42%) | catalogued as rs772754152, COSV64875971, COSV64879031; called by muse, mutect2, varscan2
- DDX60L | c.3452A>T p.D1151V | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs752251571, COSV52708434; called by muse, mutect2, varscan2
- EGFR | c.1922C>A p.P641H | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as COSV51767481; called by muse, mutect2, varscan2
- FAM172A | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs772453876, COSV67933674; called by muse, mutect2, varscan2
- KIAA1109 | c.11158G>T p.D3720Y | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV52661622; called by muse, mutect2, varscan2
- MCM6 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51464752; called by muse, mutect2, varscan2
- MYH4 | c.2027G>T p.C676F | Missense Mutation (SNP) | VAF 94/335 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV55111575; called by muse, varscan2
- MYO9A | c.1717G>C p.E573Q | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV61847258; called by muse, mutect2, varscan2
- NOTCH3 | c.763G>T p.V255F | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54632130; called by muse, mutect2
- SELENOT | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | catalogued as COSV71982229; called by muse, mutect2, varscan2
- SPRTN | c.1310G>A p.S437N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV50477510; called by muse, mutect2, varscan2
- TAF1L | c.3363G>T p.K1121N | Missense Mutation (SNP) | VAF 100/294 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV54256472, COSV99644992; called by muse, mutect2, varscan2
- TEAD4 | c.1218G>C p.E406D | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV63279945, COSV63280417; called by muse, mutect2, varscan2
- TTC17 | c.921G>T p.M307I | Missense Mutation (SNP) | VAF 123/179 reads (69%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.844); catalogued as COSV50005759; called by muse, varscan2
- UTRN | c.8557+2T>C p.X2853_splice | Splice Site (SNP) | VAF 31/79 reads (39%) | catalogued as COSV62306968; called by muse, mutect2, varscan2
- WDR70 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 90/273 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs112033041, COSV54265579; called by muse, mutect2, varscan2
- MUC16 | c.36313G>A p.E12105K | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); called by muse, mutect2
- SND1 | c.615_616insGG p.S206Gfs*85 | Frame Shift Ins (INS) | VAF 177/1230 reads (14%) | called by mutect2, varscan2*
- TAF15 | c.1217G>T p.R406I (on ENST00000605844 / NM_139215.3; = p.R403I on NM_003487.4) | Missense Mutation (SNP) | VAF 92/296 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- TUBB1 | c.581_596del p.E194Vfs*17 | Frame Shift Del (DEL) | VAF 195/871 reads (22%) | called by mutect2, pindel, varscan2
- CSN1S1 | c.270G>C p.S90= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV55889654, COSV55890366; called by muse, mutect2, varscan2
- STOX2 | c.2016T>C p.A672= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV57848476; called by muse, mutect2, varscan2
- TTN | c.90744T>A p.A30248= (on ENST00000591111; = p.A22824= on NM_003319.4) | Silent (SNP) | VAF 96/381 reads (25%) | catalogued as COSV59870476; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824590 A>T | 5'Flank (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
